TCGA case TCGA-VT-A80J — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Vanderbilt. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5370ed4a-eb6b-4eb4-8c71-f5b5d75cfa2d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Alive.

Diagnoses (3)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 49.1 years (17,925 days); Year of diagnosis: 2012; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lymph Node, Inguinal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 9.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 5; Tumor width measurement: 3.
   Pathology details: Measurement type: Radiologic; Tumor burden: 9.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 45; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5; Tumor length measurement: 9; Tumor width measurement: 5.
2. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 47.3 years (17,284 days); Days to diagnosis: -641 days (-1.8 years).
3. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lymph nodes of inguinal region or leg. Age at diagnosis: 50.0 years (18,280 days); Days to diagnosis: 355 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.5; Tumor length measurement: 3.2; Tumor width measurement: 1.5.
   Pathology details: Measurement type: Radiologic; Tumor burden: 4.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 4; Tumor width measurement: 2.
   Pathology details: Measurement type: Pathologic; Tumor burden: 4.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 3.
- Day 355 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of inguinal region or leg; Days to progression: 355 days.
- Days to follow up: 545 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 796 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 41.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VT-A80J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-VT-A80J-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VT-A80J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VT-A80J-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: OCT; Initial weight: 330 mg.
  Slide TCGA-VT-A80J-02A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VT-A80J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-VT-A80J-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-VT-A80J-11A-02-TS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Discontinuous lesions count: 3; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: inguinal lymph node.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 5; Lesion radiologic width: 3; Lesion radiologic depth: 2; Lesion pathologic length: 9; Lesion pathologic width: 5; Lesion pathologic depth: 5.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Stable Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Multilocular Cystic Renal Cell Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Left, Radical Nephrectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 796 days; disease-specific survival: no event (censored), 796 days; disease-free interval: event (new tumor event after initially disease-free), 355 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 355 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VT-A80J-01A-11D-A36I-01): tumor purity 0.37, ploidy 1.6, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VT-A80J-02A-11D-A416-01): tumor purity 0.8, ploidy 2.82, whole-genome doublings 1.
